Somatic mutation profile of tumor specimen TCGA-4V-A9QQ-01A (aliquot TCGA-4V-A9QQ-01A-11D-A423-09) from TCGA case TCGA-4V-A9QQ, project TCGA-THYM (Thymoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Thymoma, type B3, malignant; Tissue or organ of origin: Thymus; Age at diagnosis: 65.4 years (23,894 days).
Specimen TCGA-4V-A9QQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 35fcbba4-5393-476b-9f3e-b29072422162.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-4V-A9QQ-10B (Blood Derived Normal), aliquot TCGA-4V-A9QQ-10B-01D-A426-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/46425cd8-80b8-479d-896a-cd69f2d2e76e

The open-access MAF lists 6 somatic variants for this specimen: 4 protein-altering or splice-affecting, 2 silent.
By variant classification: Nonsense Mutation 2, Silent 2, Missense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKT1 | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.515); catalogued as COSV62573390; called by muse, mutect2, varscan2
- STAG2 | c.891C>A p.Y297* | Nonsense Mutation (SNP) | VAF 14/102 reads (14%) | catalogued as COSV54351526; called by muse, mutect2, varscan2
- DNAH3 | c.347T>A p.L116* | Nonsense Mutation (SNP) | VAF 8/55 reads (15%) | called by muse, mutect2, varscan2
- HERC1 | c.882del p.S295Afs*6 | Frame Shift Del (DEL) | VAF 9/85 reads (11%) | called by mutect2, pindel
- KCND1 | c.327G>A p.E109= | Silent (SNP) | VAF 3/42 reads (7%) | called by muse, mutect2
- ZNF81 | c.735C>T p.F245= | Silent (SNP) | VAF 16/184 reads (9%) | catalogued as COSV100096082; called by muse, mutect2
